Somatic mutation profile of tumor specimen ALCH-B2VP-TTP1-A (aliquot ALCH-B2VP-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2VP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 82.7 years (30,189 days).
Specimen ALCH-B2VP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 740c7f46-5c77-420e-a554-a8c75ef3e6b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2VP-NB1-A (Blood Derived Normal), aliquot ALCH-B2VP-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9ebced8-4ed1-415e-a2df-38bd7e55ff01

The open-access MAF lists 83 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Intron 6, 3'UTR 5, Nonsense Mutation 4, RNA 3, Splice Site 3, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 10/274 reads (4%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2
- CROCC | c.3698G>A p.R1233H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1227996959, COSV65013804; called by muse, mutect2
- DCAF4L2 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as rs1024363041; called by muse, mutect2
- DLL1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64537663; called by muse, mutect2
- ELFN2 | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.034); catalogued as COSV68746642; called by muse, mutect2
- GCGR | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315813878, COSV68779644; called by muse, mutect2
- GPNMB | c.1201C>T p.P401S (on ENST00000381990 / NM_001005340.2; = p.P389S on NM_002510.3) | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV51699350; called by muse, mutect2
- MID2 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 9/202 reads (4%) | catalogued as COSV99464150; called by muse, mutect2
- MRAS | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56670813; called by muse, mutect2
- NF1 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 12/288 reads (4%) | catalogued as COSV62224906; called by muse, mutect2
- PRSS1 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 23/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61196964; called by muse, mutect2
- SLC2A9 | c.682-1G>T p.X228_splice | Splice Site (SNP) | VAF 20/419 reads (5%) | catalogued as COSV99304182; called by muse, mutect2
- XKR5 | c.701C>A p.T234N | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV68399022; called by muse, mutect2
- ADAMTS6 | c.2504G>T p.S835I | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2
- AKR1C8P | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- ANKFN1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.543); called by muse, mutect2
- BDNF | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- BRDT | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2
- BTK | c.542A>T p.H181L | Missense Mutation (SNP) | VAF 15/544 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2
- C10orf67 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DAP3 | c.273G>A p.V91= | Splice Region (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- DNAH8 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2
- DOCK8 | c.2281G>T p.D761Y | Missense Mutation (SNP) | VAF 22/686 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- DZIP1L | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- GATA3 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 19/559 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- HPS5 | c.2345T>G p.F782C (on ENST00000349215 / NM_181507.2; = p.F668C on NM_007216.4) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLV2-18 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- IRF8 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 15/550 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2
- LRRC8D | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LRRN3 | c.743T>A p.L248H | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- MAGEA11 | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- MEGF10 | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); called by muse, mutect2
- MTRR | c.1935G>T p.E645D (on ENST00000264668; = p.E618D on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); called by muse, mutect2
- NFASC | c.1078G>T p.A360S (on ENST00000339876 / NM_001378329.1; = p.A371S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- NFASC | c.1854C>A p.N618K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2
- OR6N1 | c.457T>A p.L153M | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- PAPPA2 | c.4276G>C p.G1426R | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PKD1L1 | c.3785-1G>A p.X1262_splice | Splice Site (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- POLQ | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SAMSN1 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- SEC61G | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- SEMA3G | c.1686G>T p.Q562H | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SHKBP1 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- SLC46A1 | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.224); called by muse, mutect2
- SLIT3 | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TENM3 | c.1316C>A p.S439Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TMEM266 | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 19/531 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV8-4 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 14/387 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.174); called by muse, mutect2
- TRDMT1 | c.323+1G>T p.X108_splice | Splice Site (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- UBTF | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZIC5 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 26/696 reads (4%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ZNF532 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALOX5 | c.951G>A p.L317= | Silent (SNP) | VAF 11/262 reads (4%) | called by muse, mutect2
- ARHGAP25 | c.711G>A p.K237= (on ENST00000409202 / NM_001007231.3; = p.K229= on NM_014882.3) | Silent (SNP) | VAF 11/211 reads (5%) | called by muse, mutect2
- CLCC1 | c.42A>T p.V14= | Silent (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- FNDC7 | c.1572C>A p.A524= | Silent (SNP) | VAF 21/276 reads (8%) | called by muse, mutect2
- FOXC2 | c.870G>T p.G290= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- GREB1 | c.5256C>T p.A1752= | Silent (SNP) | VAF 18/341 reads (5%) | catalogued as rs773946129, COSV99303149; called by muse, mutect2
- KTI12 | c.723G>T p.L241= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- NXF3 | c.1419G>T p.R473= | Silent (SNP) | VAF 18/486 reads (4%) | called by muse, mutect2
- PRSS12 | c.1275T>C p.C425= | Silent (SNP) | VAF 20/520 reads (4%) | called by muse, mutect2
- SORL1 | c.2871G>T p.L957= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- SPDYE3 | c.1267C>T p.L423= | Silent (SNP) | VAF 19/839 reads (2%) | called by muse, mutect2
- STAB1 | c.1056G>T p.G352= | Silent (SNP) | VAF 14/308 reads (5%) | catalogued as COSV58741917; called by muse, mutect2
- STK38L | c.231C>T p.F77= | Silent (SNP) | VAF 10/237 reads (4%) | called by muse, mutect2
- TNFRSF4 | c.717G>T p.L239= | Silent (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- VWA3B | c.3681C>T p.S1227= | Silent (SNP) | VAF 16/340 reads (5%) | catalogued as rs1185493332; called by muse, mutect2
- AC011525.1 | n.787T>A | RNA (SNP) | VAF 16/476 reads (3%) | called by muse, mutect2
- AP000356.3 | n.725G>T | RNA (SNP) | VAF 19/541 reads (4%) | called by muse, mutect2
- CMA1 | c.*20C>A | 3'UTR (SNP) | VAF 17/348 reads (5%) | called by muse, mutect2
- GNAO1 | c.723+3991C>T | Intron (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- HNF4A | c.1129+45C>A | Intron (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- HNF4A | c.1129+46C>A | Intron (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
- MID1 | c.*5C>T | 3'UTR (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- NCAN | c.*185C>A | 3'UTR (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- OR2L1P | n.647C>A | RNA (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- RADIL | c.2291-28C>T | Intron (SNP) | VAF 16/242 reads (7%) | catalogued as rs1156801845, COSV68201458; called by muse, mutect2
- RAPGEF1 | c.1855-1823C>T | Intron (SNP) | VAF 11/222 reads (5%) | called by muse, mutect2
- RN7SL495P | chr15:22611236 G>T | 5'Flank (SNP) | VAF 37/1084 reads (3%) | called by muse, mutect2
- SNORD116-17 | chr15:25087811 G>T | 3'Flank (SNP) | VAF 16/470 reads (3%) | called by muse, mutect2
- TMEM252 | c.*32C>A | 3'UTR (SNP) | VAF 13/290 reads (4%) | called by muse, mutect2
- TMEM252 | c.*31C>A | 3'UTR (SNP) | VAF 13/294 reads (4%) | catalogued as COSV101051065; called by muse, mutect2
- ZEB1 | c.58+44204G>A | Intron (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
